Somatic mutation profile of tumor specimen TCGA-CN-4729-01A (aliquot TCGA-CN-4729-01A-01D-1434-08) from TCGA case TCGA-CN-4729, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 73.1 years (26,713 days).
Specimen TCGA-CN-4729-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d6817989-6a06-4264-9d6b-03a517a20e91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4729-10A (Blood Derived Normal), aliquot TCGA-CN-4729-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9c5f1a95-3ad9-439c-b0d6-8d573f66bac6

The open-access MAF lists 151 somatic variants for this specimen: 106 protein-altering or splice-affecting, 41 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 89, Silent 41, Frame Shift Del 4, Nonsense Mutation 3, In Frame Del 3, Splice Site 3, Splice Region 2, Frame Shift Ins 2, Intron 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 23/88 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- AJAP1 | c.1088C>T p.A363V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV100982048; called by muse, mutect2, varscan2
- AKAP6 | c.2846A>T p.D949V | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs759055762, COSV55228031; called by muse, mutect2, varscan2
- AMMECR1L | c.398A>G p.N133S | Missense Mutation (SNP) | VAF 24/324 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs751015471, COSV55761607; called by muse, mutect2
- ANKRD17 | c.4987G>C p.E1663Q | Missense Mutation (SNP) | VAF 19/230 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.039); catalogued as COSV58226176; called by muse, mutect2
- ANKRD26 | c.3277G>A p.G1093S | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV65775580; called by muse, mutect2
- ARNT | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as COSV55013444; called by muse, mutect2, varscan2
- ASPM | c.4214G>A p.R1405H | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs143092798, COSV54141357; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- B3GALT4 | c.374G>T p.G125V | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV101005720; called by muse, mutect2, varscan2
- BIN1 | c.737C>T p.A246V (on ENST00000316724 / NM_001320642.1; = p.A215V on NM_004305.4) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as rs375697182; called by muse, mutect2, varscan2
- BRINP3 | c.1267A>T p.T423S | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.099); catalogued as COSV100819519; called by muse, mutect2, varscan2
- CACNA1C | c.1479G>T p.L493= | Splice Region (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100222451; called by muse, mutect2, varscan2
- CASP8AP2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 33/279 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs374867724; called by muse, mutect2, varscan2
- CCDC102B | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 11/110 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.13); catalogued as COSV100103802, COSV100104969; called by muse, mutect2
- CCDC102B | c.1097G>T p.R366M | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100103939, COSV60151170; called by muse, mutect2, varscan2
- CCDC70 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 26/209 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs776258427, COSV54429901; called by muse, mutect2, varscan2
- CCZ1 | c.1307A>T p.D436V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100382981; called by mutect2, varscan2
- CEMIP | c.2764G>A p.V922M | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV54998499; called by muse, mutect2, varscan2
- COL4A3 | c.2948T>A p.L983H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.059); catalogued as COSV100516870; called by muse, mutect2
- CRACD | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs759567560, COSV99950045; called by muse, mutect2, varscan2
- CUL9 | c.1441C>T p.L481F | Missense Mutation (SNP) | VAF 41/277 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99336094; called by muse, mutect2, varscan2
- CYP26B1 | c.755G>A p.R252Q | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as rs767790315, COSV50011098; called by muse, mutect2, varscan2
- DMD | c.3202G>A p.D1068N | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV100822938; called by muse, mutect2, varscan2
- DNMT3A | c.1473G>C p.E491D | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99264714; called by muse, mutect2, varscan2
- EFS | c.1478G>A p.R493Q | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368461770; called by muse, mutect2, varscan2
- EIF3B | c.1999G>A p.V667I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as rs1433522894, COSV62804444; called by muse, mutect2, varscan2
- EPS15 | c.2607G>C p.Q869H | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV65544712; called by muse, mutect2, varscan2
- FAM124B | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.26); PolyPhen benign (0.382); catalogued as COSV54739696; called by muse, mutect2, varscan2
- FAT3 | c.4504G>C p.D1502H | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53096910, COSV53158864; called by muse, mutect2, varscan2
- FAT4 | c.6803T>C p.V2268A | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV100630282; called by muse, mutect2, varscan2
- GABRB2 | c.85G>T p.D29Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as rs775606746, COSV50923235; called by muse, mutect2, varscan2
- GCC2 | c.321G>C p.E107D | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV100565657; called by mutect2, varscan2
- GHRHR | c.113A>G p.E38G | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV58197776; called by muse, mutect2, varscan2
- GIPR | c.1213C>G p.R405G | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.247); catalogued as COSV54424702, COSV99624967; called by muse, mutect2, varscan2
- GJA10 | c.877C>G p.R293G | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV101005454; called by muse, mutect2, varscan2
- GPAT2 | c.1668C>T p.G556= | Splice Region (SNP) | VAF 9/75 reads (12%) | catalogued as rs1270691276, COSV64003179; called by muse, mutect2, varscan2
- GRIA2 | c.2545G>T p.A849S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52401995; called by muse, mutect2, varscan2
- GSDMC | c.119G>A p.R40Q | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.041); catalogued as rs754298748, COSV52693400; called by muse, mutect2, varscan2
- HDX | c.803T>C p.L268S | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52981603; called by muse, mutect2, varscan2
- HELB | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.719); catalogued as COSV99922241; called by muse, mutect2, varscan2
- HMCES | c.758C>G p.S253C | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101077404; called by muse, mutect2
- IL36G | c.212G>C p.R71T | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV52079241, COSV99381268; called by muse, mutect2, varscan2
- ISYNA1 | c.954C>A p.F318L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99526351; called by muse, mutect2, varscan2
- KRTAP4-5 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV100576842, COSV58351676; called by muse, mutect2, varscan2
- LTN1 | c.1354C>A p.Q452K | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as COSV63734914; called by muse, mutect2, varscan2
- MAGI2 | c.928A>T p.M310L | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV62688959; called by muse, mutect2, varscan2
- MARCHF6 | c.1897-2A>T p.X633_splice | Splice Site (SNP) | VAF 66/183 reads (36%) | catalogued as COSV56885757; called by muse, mutect2, varscan2
- MICU3 | c.953C>T p.T318I | Missense Mutation (SNP) | VAF 55/208 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.416); catalogued as rs772470650, COSV58848198; called by muse, mutect2, varscan2
- MMRN2 | c.2686C>T p.P896S | Missense Mutation (SNP) | VAF 33/336 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.086); catalogued as COSV64401207; called by muse, mutect2, varscan2
- MYOCD | c.1338C>G p.F446L | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV100591469; called by muse, mutect2
- NCK2 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99257056; called by muse, mutect2, varscan2
- NTRK2 | c.792C>G p.I264M | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99458747; called by muse, mutect2
- ODF2L | c.63A>G p.I21M | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.208); catalogued as rs780629034, COSV54017500; called by muse, mutect2
- OR13G1 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100687571; called by muse, mutect2
- OR1G1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs1273881726, COSV61030501; called by muse, mutect2
- OR2A7 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.32); catalogued as rs563809294, COSV101512209; called by muse, mutect2, varscan2
- PACC1 | c.208C>T p.L70F | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1393482660, COSV54789224; called by muse, mutect2, varscan2
- PADI3 | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100968605; called by muse, mutect2
- PAXBP1 | c.1549G>T p.D517Y | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs778420280, COSV51608442, COSV51611603; called by muse, mutect2, varscan2
- PCDHAC1 | c.2413C>A p.H805N | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99169839; called by muse, mutect2, varscan2
- PCDHGB1 | c.1839C>A p.F613L | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99547449; called by muse, mutect2, varscan2
- PEX11A | c.57-1G>C p.X19_splice | Splice Site (SNP) | VAF 16/200 reads (8%) | catalogued as COSV99175846; called by muse, mutect2
- PHLPP2 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs377712192; called by muse, mutect2, varscan2
- PIAS3 | c.1055C>G p.A352G | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV57908275; called by muse, mutect2, varscan2
- PIWIL2 | c.2143del p.Q715Rfs*22 | Frame Shift Del (DEL) | VAF 27/122 reads (22%) | catalogued as COSV63252186; called by mutect2, pindel, varscan2
- PRAMEF12 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs752095583, COSV63215039; called by muse, mutect2, varscan2
- ROCK1 | c.3814C>A p.H1272N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101296631; called by muse, mutect2
- SAMD9 | c.1934A>T p.E645V | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV101180384; called by muse, mutect2, varscan2
- SENP1 | c.1291A>T p.I431L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as COSV50302911; called by muse, mutect2, varscan2
- SKIV2L | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs779670171, COSV64813595; called by muse, mutect2, varscan2
- SLC2A3 | c.1084A>T p.M362L | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV50006101; called by muse, mutect2
- SMG6 | c.551G>A p.G184E | Missense Mutation (SNP) | VAF 144/775 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV53973400; called by muse, mutect2, varscan2
- SP5 | c.1030C>T p.Q344* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | catalogued as rs1338529304, COSV100935369; called by muse, mutect2, varscan2
- SPDL1 | c.1724C>G p.S575* | Nonsense Mutation (SNP) | VAF 32/113 reads (28%) | catalogued as rs746010239, COSV54669296, COSV99517405, COSV99517776; called by muse, mutect2, varscan2
- SPIDR | c.765G>C p.K255N | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV52387216; called by muse, mutect2, varscan2
- SRPRA | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.889); catalogued as COSV99703097; called by muse, mutect2
- STAC3 | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 24/380 reads (6%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.981); catalogued as COSV60415881; called by muse, mutect2
- SVIL | c.4481C>T p.A1494V (on ENST00000355867 / NM_021738.3; = p.A1068V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs753738627, COSV63445056; called by muse, mutect2, varscan2
- TENM4 | c.3052C>T p.R1018C | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs953382937, COSV53659340; called by muse, mutect2, varscan2
- TOGARAM2 | c.1898C>G p.S633* | Nonsense Mutation (SNP) | VAF 5/16 reads (31%) | catalogued as COSV101091509; called by muse, mutect2, varscan2
- TRIM42 | c.1292A>T p.K431M | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99648861; called by muse, mutect2
- TTN | c.90121G>C p.D30041H (on ENST00000591111; = p.D22617H on NM_003319.4) | Missense Mutation (SNP) | VAF 66/315 reads (21%) | PolyPhen probably damaging (0.999); catalogued as COSV60267987; called by muse, mutect2, varscan2
- TTN | c.64070C>T p.S21357L (on ENST00000591111; = p.S13933L on NM_003319.4) | Missense Mutation (SNP) | VAF 6/91 reads (7%) | PolyPhen benign (0.079); catalogued as COSV100631079; called by muse, mutect2
- UACA | c.2683C>G p.Q895E | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.05); catalogued as rs758008300, COSV100537793; called by muse, mutect2, varscan2
- VANGL2 | c.1275A>T p.E425D | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs760609933, COSV63605223; called by muse, mutect2, varscan2
- XIRP1 | c.3274G>T p.G1092C | Missense Mutation (SNP) | VAF 17/131 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.593); catalogued as COSV61137157, COSV61141781; called by muse, mutect2, varscan2
- XKR4 | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as COSV100534134; called by muse, mutect2, varscan2
- ZBTB32 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.052); catalogued as COSV99386279; called by muse, mutect2, varscan2
- ZFP91 | c.800A>T p.E267V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1025701491, COSV60161286; called by muse, mutect2
- ZNF264 | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV54043246; called by muse, mutect2, varscan2
- ZNF544 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV99517280; called by muse, mutect2, varscan2
- ZNF547 | c.945G>C p.Q315H | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56580570, COSV99988167; called by muse, mutect2, varscan2
- ZNF708 | c.1291A>G p.I431V | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs149009596; called by muse, mutect2, varscan2
- ZNF875 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs200183559, COSV100183564; called by muse, mutect2, varscan2
- ZYG11B | c.80C>T p.T27I | Missense Mutation (SNP) | VAF 19/181 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV53756202; called by muse, mutect2, varscan2
- AOC1 | c.213_224del p.I72_L75del | In Frame Del (DEL) | VAF 28/198 reads (14%) | called by mutect2, pindel
- CNTNAP5 | c.1534_1536del p.C512del | In Frame Del (DEL) | VAF 11/110 reads (10%) | called by mutect2, pindel
- CREB3L3 | c.1062_1072+10del p.X354_splice | Splice Site (DEL) | VAF 10/57 reads (18%) | called by mutect2, pindel
- FCGBP | c.12031G>C p.G4011R | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- PRDM15 | c.3279dup p.T1094Yfs*4 | Frame Shift Ins (INS) | VAF 13/50 reads (26%) | called by mutect2, pindel, varscan2
- SATB2 | c.1053dup p.E352Rfs*20 | Frame Shift Ins (INS) | VAF 55/237 reads (23%) | called by mutect2, pindel, varscan2
- SENP6 | c.2644del p.Q882Rfs*18 | Frame Shift Del (DEL) | VAF 55/336 reads (16%) | called by mutect2, pindel, varscan2
- SLC16A9 | c.996_998del p.R332del | In Frame Del (DEL) | VAF 12/109 reads (11%) | called by pindel, varscan2
- TCP11L1 | c.481del p.D161Ifs*4 | Frame Shift Del (DEL) | VAF 11/79 reads (14%) | called by mutect2, pindel, varscan2
- TTN | c.13444_13445del p.S4482Qfs*3 (on ENST00000591111; = p.S3555Qfs*3 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/122 reads (18%) | called by pindel, varscan2
- BEND2 | c.126A>T p.I42= | Silent (SNP) | VAF 29/64 reads (45%) | catalogued as COSV66215854, COSV66216885; called by muse, mutect2, varscan2
- CALCA | c.300C>T p.F100= | Silent (SNP) | VAF 31/180 reads (17%) | catalogued as COSV100524120; called by muse, mutect2, varscan2
- COL4A3 | c.2949C>G p.L983= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as COSV100516614, COSV100516873; called by muse, mutect2
- CTSH | c.105C>T p.F35= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV54985020, COSV99585676; called by muse, mutect2, varscan2
- CUL9 | c.1440C>T p.Y480= | Silent (SNP) | VAF 39/275 reads (14%) | catalogued as COSV99336091; called by muse, mutect2, varscan2
- ELFN2 | c.1041G>A p.T347= | Silent (SNP) | VAF 53/205 reads (26%) | catalogued as rs759468646, COSV68743981; called by muse, mutect2, varscan2
- ERBB4 | c.663C>T p.C221= | Silent (SNP) | VAF 34/163 reads (21%) | catalogued as COSV99633676; called by muse, mutect2, varscan2
- FAM135B | c.1200C>A p.G400= | Silent (SNP) | VAF 66/236 reads (28%) | catalogued as COSV52746739; called by muse, mutect2, varscan2
- FRMD6 | c.1635C>T p.L545= (on ENST00000344768 / NM_001267046.2; = p.L537= on NM_152330.4) | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as rs1179548355, COSV100656348; called by muse, mutect2
- HELB | c.24G>T p.L8= | Silent (SNP) | VAF 18/115 reads (16%) | catalogued as COSV99922238; called by muse, mutect2, varscan2
- IL1RAP | c.1158C>T p.V386= | Silent (SNP) | VAF 21/132 reads (16%) | catalogued as rs747892067, COSV50768045, COSV99299412; called by muse, mutect2, varscan2
- IQSEC3 | c.1464C>T p.V488= (on ENST00000538872 / NM_001170738.2; = p.V185= on NM_015232.1) | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV100407652; called by muse, mutect2, varscan2
- ITGA2 | c.723G>A p.Q241= | Silent (SNP) | VAF 46/135 reads (34%) | catalogued as COSV56865163; called by muse, mutect2, varscan2
- ITGB5 | c.1599C>T p.C533= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as rs1476922386, COSV56153010; called by muse, mutect2, varscan2
- KDM1B | c.1782C>T p.L594= (on ENST00000449850; = p.L362= on NM_153042.4) | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as rs1182604798, COSV52813723; called by muse, mutect2, varscan2
- L3MBTL2 | c.1698C>T p.L566= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs776645863, COSV99346178; called by muse, mutect2, varscan2
- LRP1B | c.5475A>G p.K1825= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as COSV67260753; called by muse, mutect2, varscan2
- MED12L | c.5019G>A p.P1673= | Silent (SNP) | VAF 16/145 reads (11%) | catalogued as rs765736163, COSV56374198, COSV99850822; called by muse, mutect2, varscan2
- MRPL49 | c.442C>A p.R148= | Silent (SNP) | VAF 39/189 reads (21%) | catalogued as COSV53696859, COSV53697914; called by muse, mutect2, varscan2
- NLRC5 | c.3565C>T p.L1189= | Silent (SNP) | VAF 103/413 reads (25%) | catalogued as COSV52661096; called by muse, mutect2, varscan2
- NLRP3 | c.2994G>C p.L998= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100276686; called by muse, mutect2, varscan2
- NPTX2 | c.435C>G p.L145= | Silent (SNP) | VAF 63/216 reads (29%) | catalogued as COSV55717285, COSV99675117; called by muse, mutect2, varscan2
- NXPE1 | c.1365C>T p.I455= (on ENST00000424269; = p.I313= on NM_152315.5) | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs758159681, COSV52628279; called by muse, mutect2, varscan2
- OR5AC2 | c.267C>T p.D89= | Silent (SNP) | VAF 61/435 reads (14%) | catalogued as COSV62280003; called by muse, mutect2, varscan2
- PCDH17 | c.426G>A p.S142= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs770674617, COSV64976722, COSV64977781; called by muse, mutect2, varscan2
- PER1 | c.1959C>T p.S653= | Silent (SNP) | VAF 41/171 reads (24%) | catalogued as rs766152619, COSV57921469; called by muse, mutect2, varscan2
- PIF1 | c.699G>A p.G233= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as rs984009166, COSV51424084; called by muse, mutect2, varscan2
- RBPJ | c.531T>C p.A177= | Silent (SNP) | VAF 48/82 reads (59%) | catalogued as COSV60755302; called by muse, mutect2, varscan2
- RNF213 | c.9678C>T p.C3226= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs768341680, COSV60406249; called by muse, mutect2, varscan2
- SEMA5A | c.2070T>C p.N690= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as COSV66802791; called by muse, mutect2, varscan2
- SEPTIN2 | c.540C>T p.V180= | Silent (SNP) | VAF 26/162 reads (16%) | catalogued as COSV63472391; called by muse, mutect2, varscan2
- SMARCB1 | c.246G>T p.T82= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as COSV54101223, COSV54102959; called by muse, mutect2, varscan2
- TRIM21 | c.618G>A p.E206= | Silent (SNP) | VAF 94/313 reads (30%) | catalogued as COSV54345790; called by muse, mutect2, varscan2
- TUFM | c.441C>T p.L147= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as rs759117049, COSV57948364; called by muse, mutect2, varscan2
- UNC5D | c.2034C>A p.L678= | Silent (SNP) | VAF 46/344 reads (13%) | catalogued as COSV54795139, COSV54825037; called by muse, mutect2, varscan2
- WRAP53 | c.759G>T p.P253= | Silent (SNP) | VAF 46/193 reads (24%) | catalogued as rs754489792, COSV56834998, COSV99872996; called by muse, mutect2, varscan2
- ZDHHC8 | c.498C>T p.F166= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as rs757892149, COSV100272913, COSV57708831; called by muse, mutect2, varscan2
- ZFP82 | c.1539G>A p.K513= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as COSV67566346; called by muse, mutect2, varscan2
- ZIC4 | c.873G>A p.S291= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV67170830, COSV67171187; called by muse, mutect2, varscan2
- ZNF319 | c.1263C>T p.P421= | Silent (SNP) | VAF 9/73 reads (12%) | catalogued as rs150126886; called by muse, mutect2
- ZNF672 | c.1191C>T p.C397= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs750359675, COSV60637762; called by muse, mutect2
- HERC2P3 | chr15:20457848 G>A | 5'Flank (SNP) | VAF 15/73 reads (21%) | called by muse, mutect2, varscan2
- IL9R | c.29-1491dup | Intron (INS) | VAF 82/353 reads (23%) | called by mutect2, pindel, varscan2
- ITGA3 | c.*124G>A | 3'UTR (SNP) | VAF 54/250 reads (22%) | catalogued as COSV50331800; called by muse, mutect2, varscan2
- WNK1 | c.2140-2525C>G | Intron (SNP) | VAF 8/155 reads (5%) | catalogued as COSV100268732; called by muse, mutect2
